Somatic mutation profile of tumor specimen TCGA-77-8130-01A (aliquot TCGA-77-8130-01A-11D-2244-08) from TCGA case TCGA-77-8130, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 69.2 years (25,260 days).
Specimen TCGA-77-8130-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22ba0ba3-da9c-44cb-9f4c-5cc424960893.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-8130-10A (Blood Derived Normal), aliquot TCGA-77-8130-10A-01D-2244-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7902feaa-3c92-48e0-a763-63d82d489575

The open-access MAF lists 198 somatic variants for this specimen: 143 protein-altering or splice-affecting, 49 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 130, Silent 49, Nonsense Mutation 6, Frame Shift Del 5, Intron 4, Frame Shift Ins 1, RNA 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABLIM1 | c.485G>T p.G162V | Missense Mutation (SNP) | VAF 42/213 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99522316; called by muse, mutect2, varscan2
- AGO4 | c.2564A>G p.Q855R | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV100943014; called by muse, mutect2, varscan2
- AHDC1 | c.2903T>A p.L968Q | Missense Mutation (SNP) | VAF 44/204 reads (22%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as COSV99899500; called by muse, mutect2, varscan2
- ATP4A | c.1289G>A p.R430Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0.24); catalogued as COSV99382800; called by muse, mutect2
- BAZ1B | c.4178G>T p.C1393F | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV100289894; called by muse, mutect2, varscan2
- BCL9 | c.3317G>C p.G1106A | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.994); catalogued as COSV99325439; called by muse, mutect2, varscan2
- BOD1L1 | c.9023G>T p.R3008I | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50006293, COSV99238189; called by muse, mutect2
- C6orf118 | c.1394G>A p.R465K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0.013); catalogued as COSV100024879, COSV100024951, COSV57813264; called by muse, mutect2, varscan2
- C6orf136 | c.19G>T p.G7C | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.674); catalogued as COSV99528070; called by muse, mutect2, varscan2
- C7orf33 | c.128G>A p.R43K | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs1477821663, COSV100188850; called by muse, mutect2
- C9orf131 | c.3043C>A p.P1015T | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.294); catalogued as COSV100398176; called by muse, varscan2
- CACNA1E | c.1367C>G p.S456C | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV100703800, COSV62382305; called by muse, mutect2, varscan2
- CADM1 | c.620T>G p.L207R | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100523000; called by muse, mutect2, varscan2
- CCDC74B | c.544G>T p.G182C | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100134569; called by mutect2, varscan2
- CCNA1 | c.1160T>C p.I387T | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.062); catalogued as COSV99714688; called by muse, mutect2, varscan2
- CDH17 | c.1828C>A p.L610I | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99217655; called by muse, mutect2, varscan2
- CEMIP2 | c.2233C>G p.P745A | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV100987425; called by muse, mutect2, varscan2
- CGB1 | c.137C>A p.T46N | Missense Mutation (SNP) | VAF 28/496 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV100031700; called by muse, mutect2
- CHD3 | c.2387C>G p.T796S | Missense Mutation (SNP) | VAF 51/178 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100391367; called by muse, mutect2, varscan2
- CHIT1 | c.104G>T p.R35I | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99705421; called by muse, mutect2, varscan2
- CIRBP | c.241C>G p.Q81E | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV100309833; called by muse, mutect2, varscan2
- CLASP1 | c.1604C>T p.A535V | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1205295247, COSV99755711; called by muse, mutect2
- CLTC | c.3374T>C p.I1125T | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99292559; called by muse, mutect2
- CMYA5 | c.11060A>G p.H3687R | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV101483944; called by muse, mutect2, varscan2
- CNTNAP5 | c.2638G>T p.E880* | Nonsense Mutation (SNP) | VAF 48/108 reads (44%) | catalogued as COSV101443775; called by muse, mutect2, varscan2
- COA8 | c.518G>T p.G173V | Missense Mutation (SNP) | VAF 50/236 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV99914932; called by muse, mutect2, varscan2
- COBL | c.1469G>C p.R490P | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV54358557, COSV99473198; called by muse, mutect2, varscan2
- COL4A4 | c.3152G>T p.G1051V | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100307215, COSV61632647; called by muse, mutect2, varscan2
- COL4A4 | c.3151G>T p.G1051C | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM143848, COSV100307217, COSV61632650, COSV61635540; called by muse, mutect2, varscan2
- CPLANE2 | c.731T>G p.V244G | Missense Mutation (SNP) | VAF 33/245 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as COSV100983278; called by muse, mutect2, varscan2
- CSMD3 | c.6196G>A p.D2066N (on ENST00000297405 / NM_001363185.1; = p.D1962N on NM_052900.3) | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.115); catalogued as COSV99839064; called by muse, mutect2, varscan2
- CXCR1 | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1434464306, COSV99826369; called by muse, mutect2
- DIO3 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63773101; called by muse, mutect2, varscan2
- DNAH3 | c.5711T>C p.F1904S | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as COSV99768725; called by muse, mutect2, varscan2
- DPYSL5 | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.078); catalogued as COSV56510891, COSV99982221; called by muse, mutect2, varscan2
- DST | c.7276C>G p.H2426D | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV99757899; called by muse, mutect2, varscan2
- DZIP3 | c.1905del p.D636Mfs*47 | Frame Shift Del (DEL) | VAF 24/79 reads (30%) | catalogued as COSV64314303; called by mutect2, pindel, varscan2
- EFCAB5 | c.3457C>G p.H1153D | Missense Mutation (SNP) | VAF 25/200 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100300442; called by muse, mutect2, varscan2
- ELAPOR2 | c.2269G>A p.V757I (on ENST00000450689 / NM_001142749.3; = p.V590I on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.028); catalogued as COSV99789073; called by muse, mutect2, varscan2
- EPB41L3 | c.2323A>G p.M775V | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1426142622, COSV100549369; called by muse, mutect2, varscan2
- EXOC3L1 | c.101T>A p.L34H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100104039; called by muse, mutect2, varscan2
- FAM160A2 | c.1276C>G p.L426V | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56413821; called by muse, mutect2, varscan2
- FAT1 | c.10645G>T p.E3549* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as COSV101499450; called by muse, mutect2, varscan2
- FCRL3 | c.1379A>G p.Q460R | Missense Mutation (SNP) | VAF 31/241 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); catalogued as COSV100943383; called by muse, mutect2, varscan2
- FGF7 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); catalogued as rs1172067015, COSV99983506; called by muse, mutect2
- GAS2L3 | c.94G>A p.V32I | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as rs769045435, COSV99902953; called by muse, mutect2, varscan2
- GPR155 | c.488C>A p.P163Q | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99790021; called by muse, mutect2, varscan2
- GRM3 | c.1539T>A p.C513* | Nonsense Mutation (SNP) | VAF 19/105 reads (18%) | catalogued as COSV100862675; called by muse, mutect2, varscan2
- H1-5 | c.333C>A p.N111K | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100137978; called by muse, mutect2, varscan2
- HABP2 | c.1130A>G p.D377G | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.012); catalogued as COSV100667989; called by muse, mutect2, varscan2
- HERC1 | c.14276A>C p.H4759P | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV101496695; called by muse, varscan2
- HK3 | c.1575C>A p.F525L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as COSV52839088, COSV52843752; called by mutect2, varscan2
- HNRNPM | c.445G>T p.D149Y | Missense Mutation (SNP) | VAF 109/272 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100335299; called by muse, varscan2
- IL25 | c.365C>G p.S122C | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs769307442, COSV100198104; called by muse, mutect2, varscan2
- INMT | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 53/271 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as rs372838601; called by muse, mutect2, varscan2
- IQCF2 | c.55G>C p.V19L | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV100291068; called by muse, mutect2, varscan2
- ITGAV | c.574G>T p.D192Y | Missense Mutation (SNP) | VAF 74/201 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV53719327, COSV99655281; called by muse, mutect2, varscan2
- ITIH1 | c.2072A>G p.N691S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as rs201884766; called by muse, varscan2
- KCTD8 | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.371); catalogued as COSV100759753, COSV63592085; called by muse, mutect2, varscan2
- KDM2B | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as rs782420924, COSV100997230, COSV100997493; called by muse, mutect2, varscan2
- KIAA1549 | c.2381A>G p.H794R | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.026); catalogued as COSV99651236; called by muse, mutect2, varscan2
- KIAA1549 | c.1156G>A p.D386N | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs566170382, COSV54334322; called by muse, mutect2, varscan2
- KNDC1 | c.2951G>T p.R984L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as COSV100465461, COSV58836199; called by muse, mutect2, varscan2
- KPNB1 | c.2249C>T p.S750L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.031); catalogued as COSV99268241; called by muse, varscan2
- LAMP3 | c.310C>G p.L104V | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as COSV99660622; called by muse, mutect2, varscan2
- LONP2 | c.1456C>T p.L486F | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV53526728, COSV99589360; called by muse, mutect2, varscan2
- LRP12 | c.1213A>T p.R405W | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV99408001; called by muse, mutect2, varscan2
- LRRC42 | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 19/56 reads (34%) | catalogued as COSV100066617; called by muse, mutect2, varscan2
- LRRC7 | c.3590C>T p.T1197I (on ENST00000651989 / NM_001370785.2; = p.T1164I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as COSV99227986; called by muse, mutect2, varscan2
- LSM8 | c.125A>G p.H42R | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.06); catalogued as COSV99972677; called by muse, mutect2, varscan2
- LTBP1 | c.4808A>T p.E1603V (on ENST00000404816 / NM_206943.4; = p.E1277V on NM_000627.4) | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV99698447; called by muse, mutect2, varscan2
- MICAL2 | c.767C>G p.A256G | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99817884; called by muse, mutect2, varscan2
- MSL2 | c.1709C>G p.A570G | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.306); catalogued as COSV99387611; called by muse, mutect2, varscan2
- NAV3 | c.1882G>A p.A628T | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as rs1348734842, COSV57065515; called by muse, mutect2, varscan2
- NBEAL1 | c.6821G>A p.C2274Y | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100074337; called by muse, mutect2
- NCAM2 | c.390A>T p.E130D | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99523833; called by muse, mutect2, varscan2
- NOD1 | c.419A>G p.D140G | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99768270; called by muse, mutect2, varscan2
- NOL8 | c.691G>T p.G231W | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV100694604; called by muse, mutect2
- NOP58 | c.219A>T p.K73N | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV99970704; called by muse, mutect2, varscan2
- NPAP1 | c.3412A>C p.T1138P | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.089); catalogued as COSV100275649; called by muse, mutect2, varscan2
- OR10S1 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs1294874537, COSV73342830; called by muse, mutect2, varscan2
- OR11G2 | c.291G>A p.M97I | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1353223014, COSV100639986; called by muse, mutect2, varscan2
- OR2M3 | c.270G>C p.K90N | Missense Mutation (SNP) | VAF 52/439 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as COSV101513471; called by muse, mutect2, varscan2
- OR2T34 | c.644C>A p.P215H | Missense Mutation (SNP) | VAF 24/410 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60900853; called by muse, mutect2
- OR4P4 | c.212A>G p.Y71C | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.32); catalogued as rs1319947362, COSV100111778; called by muse, mutect2, varscan2
- PCDHB7 | c.1278G>C p.L426F | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.247); catalogued as COSV50830323, COSV99177127; called by muse, mutect2, varscan2
- PDGFRA | c.309C>G p.N103K | Missense Mutation (SNP) | VAF 39/391 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.136); catalogued as COSV99957072; called by muse, mutect2, varscan2
- PHKB | c.2691G>T p.L897F | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as COSV100067832; called by muse, mutect2, varscan2
- PLXNA2 | c.5381C>T p.P1794L | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100885622; called by muse, mutect2
- PPP1R13L | c.1481A>G p.Q494R | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.07); catalogued as COSV100714806; called by muse, mutect2
- PRB2 | c.860C>G p.P287R | Missense Mutation (SNP) | VAF 66/298 reads (22%) | SIFT tolerated (0.89); PolyPhen benign (0.015); catalogued as rs749642828, COSV101231451, COSV66983747; called by muse, varscan2
- PRDM9 | c.1874C>A p.T625N | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.018); catalogued as COSV99690694; called by muse, varscan2
- PRDM9 | c.2347C>T p.R783W | Missense Mutation (SNP) | VAF 24/206 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs566721769, COSV57005773, COSV99690900; called by muse, varscan2
- RABEP2 | c.365T>C p.L122P | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100707119; called by muse, varscan2
- RAPGEF2 | c.1739G>A p.G580E | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.76); catalogued as COSV100031380; called by muse, mutect2, varscan2
- REG3A | c.148C>T p.H50Y | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100532643, COSV100532800, COSV59408769; called by muse, mutect2, varscan2
- RHCG | c.803C>G p.S268C | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV99174144; called by muse, mutect2
- RNF125 | c.431G>T p.C144F | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV99470561; called by muse, mutect2, varscan2
- RPAP1 | c.3712C>G p.R1238G | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV100427210; called by muse, mutect2, varscan2
- RUVBL2 | c.688G>T p.G230W | Missense Mutation (SNP) | VAF 53/333 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99669103; called by muse, mutect2, varscan2
- RXRG | c.669G>C p.E223D | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.905); catalogued as COSV100717684, COSV63233297; called by muse, mutect2, varscan2
- RYR2 | c.9913C>T p.P3305S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV100771632; called by muse, mutect2, varscan2
- SCN7A | c.3016G>C p.V1006L | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV101313285; called by muse, mutect2, varscan2
- SIGLEC7 | c.1340C>A p.P447H | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV58315614, COSV99978809; called by muse, mutect2, varscan2
- SLC22A16 | c.340T>C p.Y114H | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.104); catalogued as COSV100397583; called by muse, mutect2, varscan2
- SLC30A9 | c.124G>A p.V42M | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as COSV100048367; called by muse, mutect2, varscan2
- SLC8A3 | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | catalogued as COSV100776224, COSV100776283; called by muse, mutect2, varscan2
- SRBD1 | c.1565G>A p.G522E | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.737); catalogued as COSV99765227; called by muse, mutect2, varscan2
- SRPK3 | c.664G>C p.V222L | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV99473267; called by muse, mutect2, varscan2
- SYNE2 | c.740G>T p.R247I | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV100420281; called by muse, mutect2, varscan2
- TDP1 | c.1582A>G p.N528D | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.153); catalogued as COSV100187949; called by muse, mutect2, varscan2
- TDRD6 | c.4919A>G p.N1640S | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as COSV100287876; called by muse, mutect2, varscan2
- TEX13A | c.1048C>A p.H350N | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs181818019, COSV100781574; called by muse, mutect2, varscan2
- THAP10 | c.602T>C p.F201S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs1567034675, COSV99997828; called by muse, mutect2, varscan2
- TIPARP | c.884A>G p.N295S | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.091); catalogued as COSV99903887; called by muse, mutect2, varscan2
- TMEM225 | c.232T>C p.F78L | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.475); catalogued as rs1565564290, COSV100902835; called by muse, mutect2, varscan2
- TNRC18 | c.6833G>A p.R2278H | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1166596074, COSV100078981, COSV60307953; called by muse, mutect2, varscan2
- TOX2 | c.1096C>G p.P366A (on ENST00000358131 / NM_001098798.2; = p.P342A on NM_032883.3) | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV100364109; called by muse, mutect2, varscan2
- TP53 | c.913A>T p.K305* | Nonsense Mutation (SNP) | VAF 48/120 reads (40%) | catalogued as COSV52688866, COSV52766207; called by muse, mutect2, varscan2
- TRBV27 | c.16C>T p.L6F | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.062); catalogued as rs768158120; called by muse, varscan2
- TTN | c.95018C>A p.P31673Q (on ENST00000591111; = p.P24249Q on NM_003319.4) | Missense Mutation (SNP) | VAF 20/40 reads (50%) | PolyPhen possibly damaging (0.777); catalogued as COSV100619834; called by muse, mutect2, varscan2
- TTPA | c.358G>C p.A120P | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.301); catalogued as CM981964, COSV99478558; called by muse, mutect2, varscan2
- UCKL1 | c.759C>G p.I253M | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.702); catalogued as COSV100700532; called by muse, mutect2, varscan2
- XYLT2 | c.1701C>A p.H567Q | Missense Mutation (SNP) | VAF 53/309 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV99191013; called by muse, mutect2, varscan2
- ZBED9 | c.3272A>G p.Q1091R | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.775); catalogued as COSV101509314; called by muse, mutect2, varscan2
- ZFHX4 | c.4438G>A p.D1480N | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV99264757; called by muse, mutect2, varscan2
- ZFHX4 | c.7841C>A p.P2614Q | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99260036; called by muse, mutect2, varscan2
- ZNF578 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs376846158; called by muse, mutect2, varscan2
- ZPBP | c.214G>T p.A72S | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV99250010; called by muse, mutect2, varscan2
- ZXDB | c.1266A>C p.E422D | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.708); catalogued as COSV100885975; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1042T>G p.F348V | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ALPP | c.1588del p.E530Rfs*60 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- BPIFB4 | c.620del p.G207Vfs*26 | Frame Shift Del (DEL) | VAF 15/88 reads (17%) | called by mutect2, pindel, varscan2
- ESRRG | c.821G>T p.R274L | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FAT1 | c.9983_9986del p.I3328Tfs*47 | Frame Shift Del (DEL) | VAF 9/53 reads (17%) | called by mutect2, pindel, varscan2
- HP1BP3 | c.295dup p.E99Gfs*3 | Frame Shift Ins (INS) | VAF 30/120 reads (25%) | called by mutect2, pindel, varscan2
- IGKV6D-41 | c.26G>T p.R9L | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- MT1B | c.101_103del p.C34del | In Frame Del (DEL) | VAF 60/334 reads (18%) | called by pindel, varscan2
- MUC2 | c.2753C>T p.A918V | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.1); called by muse, mutect2, varscan2
- PSD | c.2336del p.G779Afs*15 | Frame Shift Del (DEL) | VAF 11/77 reads (14%) | called by mutect2, pindel, varscan2
- STARD8 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0); called by mutect2, varscan2
- TRAV18 | c.116C>G p.T39R | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- UBE2NL | c.174A>T p.L58F | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCER1 | c.594C>T p.Y198= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as rs371219587, COSV100727023, COSV62647514; called by muse, mutect2, varscan2
- CHST5 | c.174C>T p.G58= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as rs1555503773, COSV60339888; called by muse, mutect2, varscan2
- DYNLT1 | c.93T>A p.G31= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as COSV100892402; called by muse, mutect2, varscan2
- EEF2K | c.1482C>A p.L494= | Silent (SNP) | VAF 20/172 reads (12%) | catalogued as COSV99533350; called by muse, mutect2, varscan2
- EML3 | c.1554C>T p.F518= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs767569389, COSV53871402; called by muse, mutect2, varscan2
- ERICH3 | c.429C>G p.S143= | Silent (SNP) | VAF 25/178 reads (14%) | catalogued as COSV100444901; called by muse, mutect2, varscan2
- GATAD2B | c.1413G>A p.Q471= | Silent (SNP) | VAF 11/119 reads (9%) | catalogued as COSV100897920; called by muse, mutect2
- GFRA1 | c.531G>A p.P177= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as rs77406058, COSV62602233; called by muse, mutect2, varscan2
- GLI2 | c.1774C>T p.L592= (on ENST00000361492 / NM_001374353.1; = p.L609= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV100083644; called by muse, mutect2, varscan2
- GLT1D1 | c.1002A>G p.Q334= (on ENST00000442111 / NM_001366889.1; = p.Q254= on NM_144669.3) | Silent (SNP) | VAF 30/125 reads (24%) | catalogued as COSV99896991; called by muse, mutect2, varscan2
- GPR68 | c.594C>T p.I198= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV99473525; called by mutect2, varscan2
- GRM1 | c.2760T>C p.N920= | Silent (SNP) | VAF 28/104 reads (27%) | catalogued as COSV99267186; called by muse, mutect2, varscan2
- HTR1E | c.351C>A p.A117= | Silent (SNP) | VAF 21/100 reads (21%) | catalogued as COSV100541178; called by muse, mutect2, varscan2
- IL12A | c.69G>T p.A23= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV99975808; called by muse, mutect2, varscan2
- INO80D | c.2916C>T p.L972= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV68960323; called by muse, mutect2, varscan2
- ITGAX | c.1038C>A p.S346= | Silent (SNP) | VAF 72/248 reads (29%) | catalogued as COSV99191872; called by muse, mutect2, varscan2
- KCNK12 | c.855G>A p.L285= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV100009891; called by muse, mutect2, varscan2
- LRFN5 | c.1131C>A p.L377= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV99984415, COSV99984526; called by muse, mutect2, varscan2
- LRP1B | c.13629C>T p.N4543= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs181564699, COSV101257990; called by muse, mutect2, varscan2
- MROH2B | c.2448G>T p.L816= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV101270787; called by muse, mutect2, varscan2
- MRPS30 | c.1254A>G p.L418= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs764476145, COSV99138159; called by muse, mutect2, varscan2
- MYO1A | c.1878C>A p.A626= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV100271059, COSV100271366; called by muse, mutect2, varscan2
- NETO2 | c.228G>A p.L76= | Silent (SNP) | VAF 34/154 reads (22%) | catalogued as COSV100292515; called by muse, mutect2, varscan2
- NLRP3 | c.762G>T p.L254= | Silent (SNP) | VAF 8/83 reads (10%) | catalogued as COSV100276324, COSV60223916; called by muse, mutect2
- NPAP1 | c.2361C>A p.P787= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV100275648; called by muse, mutect2, varscan2
- OR2AK2 | c.912G>A p.L304= | Silent (SNP) | VAF 32/83 reads (39%) | catalogued as COSV63559854; called by muse, mutect2, varscan2
- OR4D11 | c.492G>A p.L164= | Silent (SNP) | VAF 42/179 reads (23%) | catalogued as COSV100506577; called by muse, mutect2, varscan2
- OR6K3 | c.615T>C p.C205= (on ENST00000368146; = p.C189= on NM_001005327.2) | Silent (SNP) | VAF 21/171 reads (12%) | catalogued as COSV100933847; called by muse, mutect2, varscan2
- PAPPA2 | c.5064C>A p.P1688= | Silent (SNP) | VAF 17/172 reads (10%) | catalogued as COSV100868368; called by muse, mutect2, varscan2
- PBXIP1 | c.729G>A p.G243= | Silent (SNP) | VAF 21/173 reads (12%) | catalogued as COSV100870100; called by muse, mutect2, varscan2
- PCDH17 | c.1485C>A p.L495= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV100931760, COSV64972095; called by muse, mutect2, varscan2
- PGLYRP2 | c.354C>A p.T118= | Silent (SNP) | VAF 16/192 reads (8%) | catalogued as COSV99484154; called by muse, mutect2
- PRM2 | c.87C>T p.H29= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as rs758881355, COSV54112766; called by muse, mutect2, varscan2
- PSG9 | c.1140T>C p.F380= | Silent (SNP) | VAF 69/273 reads (25%) | catalogued as COSV99392416; called by muse, mutect2, varscan2
- PSME3IP1 | c.216G>A p.Q72= | Silent (SNP) | VAF 21/137 reads (15%) | catalogued as COSV100483709; called by muse, mutect2, varscan2
- PTCHD4 | c.2073C>T p.S691= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs377487295; called by muse, mutect2, varscan2
- PTPRN2 | c.2253G>A p.A751= | Silent (SNP) | VAF 44/294 reads (15%) | catalogued as rs199567899, COSV67049886; called by muse, mutect2, varscan2
- REG3A | c.330A>T p.T110= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as COSV100532799; called by muse, mutect2, varscan2
- RYR3 | c.3435G>A p.G1145= | Silent (SNP) | VAF 28/184 reads (15%) | catalogued as COSV101212719; called by muse, mutect2, varscan2
- SLC2A14 | c.111C>T p.A37= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV100533892; called by muse, mutect2, varscan2
- SLC35F6 | c.669C>T p.L223= | Silent (SNP) | VAF 33/69 reads (48%) | catalogued as COSV100733682; called by muse, mutect2, varscan2
- SLC7A13 | c.189A>G p.S63= | Silent (SNP) | VAF 33/54 reads (61%) | catalogued as COSV99879018; called by muse, mutect2, varscan2
- SMO | c.1539G>T p.P513= | Silent (SNP) | VAF 24/133 reads (18%) | catalogued as COSV50840098, COSV99976849; called by muse, mutect2, varscan2
- SRRM4 | c.651C>A p.S217= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV99938820; called by muse, mutect2
- TAAR1 | c.585T>C p.F195= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs1383923274, COSV99257660; called by muse, mutect2, varscan2
- TGM5 | c.1122C>T p.G374= (on ENST00000220420 / NM_201631.4; = p.G292= on NM_004245.4) | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs775371115, COSV99589114; called by muse, mutect2, varscan2
- TLR4 | c.969A>G p.V323= (on ENST00000355622 / NM_138554.5; = p.V283= on NM_003266.4) | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100790668; called by muse, mutect2, varscan2
- ZFHX4 | c.840T>C p.C280= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV99264754; called by muse, mutect2, varscan2
- ZNF562 | c.1005A>T p.V335= (on ENST00000453372 / NM_001130032.2; = p.V263= on NM_017656.4) | Silent (SNP) | VAF 8/134 reads (6%) | catalogued as COSV99530754; called by muse, mutect2
- ATP6AP1L | n.1344A>G | RNA (SNP) | VAF 29/77 reads (38%) | catalogued as rs748964640, COSV101205137; called by muse, mutect2, varscan2
- DST | c.4297-3736A>G | Intron (SNP) | VAF 10/52 reads (19%) | catalogued as rs764590338, COSV55004306; called by mutect2, varscan2
- ETNK1 | c.-185A>T | 5'UTR (SNP) | VAF 8/39 reads (21%) | catalogued as COSV99860838; called by muse, mutect2, varscan2
- NACA | c.71-3566G>A | Intron (SNP) | VAF 8/20 reads (40%) | catalogued as rs1449325604, COSV100771437; called by muse, mutect2, varscan2
- TTN | c.10360+1238C>A | Intron (SNP) | VAF 43/102 reads (42%) | catalogued as COSV60000437; called by muse, mutect2, varscan2
- VPS50 | c.942+20C>G | Intron (SNP) | VAF 5/20 reads (25%) | catalogued as COSV99298297; called by muse, mutect2, varscan2
